Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4691, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4691-01A (Primary Tumor).

TCGA--B0-4691

FINAL DIAGNOSIS

KIDNEY, LEFT, NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, PREDOMINANTLY CLEAR CELL TYPE WITH FOCAL AREAS SHOWING SARCOMATOID DIFFERENTIATION AND MORPHOLOGY RESEMBLING A CHROMOPHOBE RENAL CELL CARCINOMA.
- B. FUHRMAN NUCLEAR GRADE IS 3 of 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 10.0 cm.
- D. THE NEOPLASM DOES NOT INVOLVE THE PERIRENAL OR PERIPELVIC ADIPOSE.
- E. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- G. NON-NEOPLASTIC KIDNEY SHOWS CHRONIC INTERSTITIAL INFLAMMATION AND GLOMERULOSCLEROSIS.

Specimen(s) Received: 1: TUMOR, 2: TUMOR CONTENTS

Final Diagnosis

PART 1 AND PART 2, BRAIN, RIGHT PARIETAL TUMOR HEMORRHAGE, RESECTION:
METASTATIC CLEAR CELL CARCINOMA.

Comment:

The tumor is morphologically identical to the described kidney renal cell CA and lung metastasis. Confirmatory immunostains can be performed if clinically indicated.

Final Diagnosis

1. LUNG, LEFT LOWER LOBE, CT-GUIDED FINE NEEDLE ASPIRATION BIOPSY:

UNSATISFACTORY FOR EVALUATION: NO PULMONARY MACROPHAGES IDENTIFIED.

2. LUNG, RIGHT LOWER LOBE, CT-GUIDED FINE NEEDLE ASPIRATION BIOPSY:

SATISFACTORY FOR INTERPRETATION.

POSITIVE FOR MALIGNANT CELLS.

POORLY DIFFERENTIATED MALIGNANT NEOPLASM SUGGESTIVE OF METASTATIC, See comment.

COMMENT:

The specimen shows poorly differentiated malignant neoplasm with vacuolated clear abundant cytoplasm. Tumor cells stain positively for vimentin, pan CK (focal), CD68, RCC (focal), and negatively for TTF-1, Melan A, S100, CD34, and desmin. The immunostain study support carcinoma diagnosis of non-lung origin, due to negativity TTF-1. The positivity of vimentin and CD68 is seen in malignant fibrous histiocytoma. However, the positivity of vimentin, pan CK and RCC immunostains suggests metastatic renal cell carcinoma. Recommend clinical and radiological correlation.

Final Diagnosis

LYMPH NODE, LEVEL 7, US-GUIDED FINE NEEDLE ASPIRATION BIOPSY:

SATISFACTORY FOR INTERPRETATION.

POSITIVE FOR MALIGNANT CELLS.

METASTATIC POORLY-DIFFERENTIATED MALIGNANCY,

Final Diagnosis

COLON, POLYP AT 15 CM., BIOPSIES -

COLONIC MUCOSA WITH MILD SURFACE HYPERPLASTIC CHANGE.

Final Diagnosis

URINE, CATHETERIZED:

SATISFACTORY FOR EVALUATION.

NEGATIVE FOR MALIGNANT CELLS.

BENIGN COLUMNAR AND UROTHELIAL CELLS.

Final Diagnosis

PART 1: COLON, POLYP AT 50 CM., POLYPECTOMY -
TUBULAR ADENOMA.

PART 2: COLON, POLYP AT 35 CM., POLYPECTOMY -
TUBULAR ADENOMA.

PART 3: COLON, POLYP AT 20 CM., POLYPECTOMY -
HYPERPLASTIC POLYP.

Source: NCI Genomic Data Commons file 6cfc16d8-e144-483d-8099-99939c5b7508 (TCGA-B0-4691.A1B82610-DDDE-421E-AB8A-0DC4D52B1BBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).